Somatic mutation profile of tumor specimen MMRF_1820_1_BM_CD138pos (aliquot MMRF_1820_1_BM_CD138pos_T1_KBS5U_L06447) from MMRF case MMRF_1820, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 49.7 years (18,153 days).
Specimen MMRF_1820_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6056ca07-bf0d-47fc-a0eb-829c1b020667.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1820_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1820_1_PB_Whole_C2_KBS5U_L06494; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b37234e1-f6db-4cf6-8f25-49dd0e04c20d

The open-access MAF lists 78 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 20, Intron 8, Silent 7, 5'UTR 5, RNA 2, Splice Region 2, 3'Flank 2, Nonsense Mutation 2, 5'Flank 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 29/88 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IGHV2-70 | c.228T>G p.D76E | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs373802343; called by muse, varscan2
- IGKJ5 | c.18A>C p.Q6H | Missense Mutation (SNP) | VAF 54/160 reads (34%) | catalogued as rs374287240; called by muse, varscan2
- IGLV3-1 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs375057861; called by muse, varscan2
- IGLV3-1 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs775733983; called by muse, varscan2
- MYH11 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs886038900, COSV55547028; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEFM | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647028; called by muse, mutect2, varscan2
- NR4A3 | c.1637G>C p.R546T | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58243832; called by muse, mutect2
- OR51Q1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.999); catalogued as rs372386488; called by muse, mutect2
- OR56A5 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as rs778078804, COSV60827030; called by muse, mutect2, varscan2
- RTP1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 82/347 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as rs376513971, COSV56617667; called by muse, mutect2, varscan2
- SLC24A3 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs767291276; called by muse, mutect2, varscan2
- TM9SF2 | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs1342539322; called by muse, mutect2, varscan2
- B4GALT3 | c.-13T>A | Splice Region (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- BHLHE41 | c.79_97del p.L27Kfs*4 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- CCDC172 | c.390A>C p.K130N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DACT1 | c.2499G>T p.M833I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DNAH2 | c.616G>C p.A206P | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2
- FOLR3 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 11/323 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); called by muse, mutect2
- GPR32 | c.937C>G p.P313A | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- GTF3C1 | c.5738C>T p.P1913L | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ICE1 | c.5911C>G p.L1971V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- IGHJ6 | c.36_37insC p.G13Rfs*? | Frame Shift Ins (INS) | VAF 22/60 reads (37%) | called by pindel, varscan2
- MEIOC | c.2311G>T p.E771* | Nonsense Mutation (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- MID1 | c.1784T>A p.I595N | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MOXD1 | c.1499G>A p.R500K | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PARN | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- PCDH15 | c.2426T>G p.V809G | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ST8SIA3 | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 7/147 reads (5%) | PolyPhen benign (0.061); called by muse, mutect2
- TMEM232 | c.216A>C p.R72S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TRIO | c.5497A>C p.R1833= | Splice Region (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- TRRAP | c.4749G>C p.Q1583H (on ENST00000359863 / NM_001244580.1; = p.Q1565H on NM_003496.3) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2
- ZNF106 | c.43A>C p.S15R | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- ADGRB3 | c.1056A>G p.S352= | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2
- CACNA1E | c.6750C>T p.L2250= (on ENST00000367573 / NM_001205293.3; = p.L2207= on NM_000721.4) | Silent (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- DISC1 | c.1383A>G p.E461= | Silent (SNP) | VAF 26/73 reads (36%) | called by muse, mutect2, varscan2
- IGHV1-24 | c.249C>T p.F83= | Silent (SNP) | VAF 71/184 reads (39%) | catalogued as rs549832881; called by muse, mutect2, varscan2
- MAGEL2 | c.2340G>A p.P780= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- PRC1 | c.402T>A p.I134= | Silent (SNP) | VAF 42/194 reads (22%) | called by muse, mutect2, varscan2
- ZNF852 | c.891A>G p.K297= | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as rs959555124; called by muse, mutect2, varscan2
- AMTN | c.*181A>C | 3'UTR (SNP) | VAF 36/95 reads (38%) | called by muse, mutect2, varscan2
- CARNMT1 | c.*531C>T | 3'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- CCNT2 | chr2:134918738 A>G | 5'Flank (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- CDS2 | c.-12G>A | 5'UTR (SNP) | VAF 4/76 reads (5%) | catalogued as COSV64790267; called by muse, mutect2
- CSNK1G1 | c.*5874G>T | 3'UTR (SNP) | VAF 4/103 reads (4%) | called by muse, mutect2
- DHRS2 | c.731+109A>C | Intron (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- DRD1 | c.*554T>G | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- EFNB3 | c.*679G>C | 3'UTR (SNP) | VAF 44/115 reads (38%) | called by muse, mutect2, varscan2
- EPPIN | c.223+20A>G | Intron (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- ETF1 | c.*2170G>A | 3'UTR (SNP) | VAF 18/62 reads (29%) | called by mutect2, varscan2
- FAM171A1 | c.*249C>T | 3'UTR (SNP) | VAF 18/122 reads (15%) | catalogued as rs1014070141; called by muse, mutect2, varscan2
- FBXO33 | c.*1034C>A | 3'UTR (SNP) | VAF 6/18 reads (33%) | catalogued as rs200435727; called by muse, varscan2
- FCRL5 | c.1681+538T>A | Intron (SNP) | VAF 28/72 reads (39%) | catalogued as rs1206456846; called by muse, mutect2, varscan2
- GRIN3A | c.*3196T>C | 3'UTR (SNP) | VAF 43/145 reads (30%) | called by muse, mutect2, varscan2
- HDC | c.720+69T>C | Intron (SNP) | VAF 38/186 reads (20%) | called by muse, mutect2, varscan2
- LTB | c.162+91G>A | Intron (SNP) | VAF 25/60 reads (42%) | catalogued as rs557400970; called by muse, mutect2, varscan2
- MAMDC2 | c.*767T>A | 3'UTR (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
- NAA25 | c.*1135T>G | 3'UTR (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- OR10J2P | n.606T>C | RNA (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- PACSIN1 | c.*2065G>A | 3'UTR (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2, varscan2
- PAWR | c.-78G>A | 5'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- PCDH10 | c.*1329A>C | 3'UTR (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- POU4F2 | c.-138C>T | 5'UTR (SNP) | VAF 6/120 reads (5%) | catalogued as COSV55583854; called by muse, mutect2
- PPP3R1 | c.-365G>A | 5'UTR (SNP) | VAF 15/34 reads (44%) | catalogued as rs1191387811; called by muse, mutect2, varscan2
- PURB | c.*5054G>A | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- RSF1 | c.*4297A>G | 3'UTR (SNP) | VAF 25/102 reads (25%) | catalogued as rs1339042999; called by muse, mutect2, varscan2
- SELENON | c.*1342C>T | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- SESTD1 | c.*3485C>T | 3'UTR (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
- SLC10A7 | chr4:146256264 A>G | 3'Flank (SNP) | VAF 6/125 reads (5%) | called by muse, mutect2
- SVEP1 | c.10504+86A>G | Intron (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- TBK1 | c.*233G>A | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- THAP2 | c.*3263A>G | 3'UTR (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- TMEM234 | c.387+40G>A | Intron (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- ZBBX | c.*88G>A | 3'UTR (SNP) | VAF 54/191 reads (28%) | catalogued as COSV100285113; called by muse, mutect2, varscan2
- ZNF300P1 | n.1217G>T | RNA (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- ZNF587 | c.-83A>T | 5'UTR (SNP) | VAF 33/118 reads (28%) | called by muse, mutect2, varscan2
- ZNF587 | c.33+127A>G | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- ZNF713 | chr7:55941767 C>G | 3'Flank (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
